Gene-level copy-number profile of tumor specimen TCGA-AM-5821-01A from TCGA case TCGA-AM-5821, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.2 years (24,903 days).
Specimen TCGA-AM-5821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.c64a77f8-0d56-4ad2-ae4e-9c3f6024ecea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AM-5821-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c29c2f31-b3d1-4f4f-9c4f-4e5da0a4f48b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 1,588; copy number 2: 52,802; copy number 4: 5,335; copy number 6: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AM-5821-01A-01D-1649-01): tumor purity 0.64, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr11:26,994,112–30,017,030, 42 genes: FIBIN, BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 39 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,261,962–42,541,926, 39 genes, copy number 6 (within-gene range 4–6): SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1.

Autosomal genes at a single copy (total copy number 1): 290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
